Somatic mutation profile of tumor specimen TCGA-CD-A4MH-01A (aliquot TCGA-CD-A4MH-01A-11D-A25D-08) from TCGA case TCGA-CD-A4MH, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 86.7 years (31,683 days).
Specimen TCGA-CD-A4MH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5a6d52b-2b5c-49e0-b2db-0265bc59497e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-A4MH-10A (Blood Derived Normal), aliquot TCGA-CD-A4MH-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d3ef262-f243-490e-8bd2-9a235e6c0e2c

The open-access MAF lists 89 somatic variants for this specimen: 61 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 25, Nonsense Mutation 6, Splice Site 2, Frame Shift Del 2, Intron 1, RNA 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV67017852; called by muse, mutect2
- ADCY4 | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as rs140912494; called by muse, mutect2, varscan2
- AEBP1 | c.3043C>A p.Q1015K | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV56259434; called by muse, mutect2, varscan2
- AMY1C | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs201967863, COSV64407042; called by muse, mutect2, varscan2
- ARMC5 | c.1669G>A p.G557S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0.279); catalogued as rs372791522; called by muse, mutect2, varscan2
- CACNA1D | c.1471A>T p.S491C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV55455981; called by muse, mutect2, varscan2
- CACNA2D1 | c.3290G>A p.G1097D (on ENST00000356253 / NM_001366867.1; = p.G1085D on NM_000722.4) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.07); catalogued as rs138331326; called by mutect2, varscan2
- CARD14 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.08); catalogued as rs1380449564, COSV60125089; called by muse, mutect2, varscan2
- CDH18 | c.488C>A p.P163Q | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV56940939; called by muse, mutect2, varscan2
- COPG1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs770080152, COSV59115449; called by muse, mutect2, varscan2
- CYP2W1 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as rs778855184, COSV58270883; called by muse, mutect2, varscan2
- DKC1 | c.1181A>C p.K394T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV101053812, COSV101053836; called by muse, mutect2, varscan2
- EEF1A1 | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV100303168; called by muse, mutect2, varscan2
- EP300 | c.6048G>A p.M2016I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.22); catalogued as COSV54338336; called by muse, mutect2, varscan2
- EVI5L | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs778590587, COSV54485629; called by muse, mutect2, varscan2
- FAM193A | c.2909A>G p.N970S | Missense Mutation (SNP) | VAF 61/103 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.203); catalogued as rs146890120; called by muse, mutect2, varscan2
- FBXO24 | c.1575G>T p.Q525H (on ENST00000241071 / NM_033506.3; = p.Q563H on NM_012172.5) | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV53827829; called by muse, mutect2, varscan2
- FOXR2 | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV59259116; called by muse, mutect2, varscan2
- FPGS | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV64675948; called by muse, mutect2, varscan2
- GFUS | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs375507364; called by muse, mutect2, varscan2
- KALRN | c.4601C>T p.T1534I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53772743; called by muse, varscan2
- KIF5C | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs532360681, COSV68482432; called by muse, mutect2, varscan2
- KPTN | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 117/213 reads (55%) | SIFT tolerated (0.77); PolyPhen benign (0.031); catalogued as rs764175521, COSV57645800; called by muse, mutect2, varscan2
- LAMA2 | c.3175-1G>A p.X1059_splice | Splice Site (SNP) | VAF 3/24 reads (13%) | catalogued as COSV70351847; called by muse, mutect2
- LETM1 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57102608; called by muse, mutect2, varscan2
- LZTS1 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs762386540, COSV56117612; called by muse, mutect2, varscan2
- MAP3K7 | c.995A>C p.D332A | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV65225257; called by muse, mutect2
- MEFV | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs104895116, CM035568, COSV54824683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSS51 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV55019784; called by muse, mutect2, varscan2
- NCEH1 | c.392C>T p.P131L (on ENST00000538775; = p.P99L on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs563352842, COSV56436003; called by muse, mutect2, varscan2
- NRXN1 | c.1757C>A p.S586* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV58446745, COSV58471632; called by muse, mutect2, varscan2
- NSUN6 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV66034175; called by muse, mutect2, varscan2
- PKD1L1 | c.1857T>A p.D619E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV56971421; called by muse, mutect2, varscan2
- PLD6 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs772007129, COSV58634239; called by muse, mutect2, varscan2
- PNCK | c.509G>A p.G170D (on ENST00000340888 / NM_001366975.1; = p.G253D on NM_001039582.3) | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV61744596; called by muse, mutect2, varscan2
- PNN | c.1088A>C p.E363A | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV53767456; called by muse, mutect2
- PROKR2 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs573392596, COSV54087847; called by muse, mutect2, varscan2
- PSME1 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); catalogued as rs1198323464, COSV52824886; called by muse, mutect2, varscan2
- RAB14 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65788534; called by muse, mutect2
- RAPGEF4 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51402601; called by muse, mutect2, varscan2
- RTL9 | c.3341C>T p.A1114V | Missense Mutation (SNP) | VAF 62/346 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as rs898978419, COSV71825388, COSV71825924; called by muse, mutect2, varscan2
- SLC26A3 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as rs776888978, COSV60639399; called by mutect2, varscan2
- SPAG17 | c.2836C>T p.R946* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | catalogued as rs201253941, COSV60463148, COSV60465006; called by muse, mutect2, varscan2
- SRRM2 | c.7228C>T p.P2410S | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51941252; called by muse, mutect2, varscan2
- ST6GAL2 | c.1303T>C p.S435P | Missense Mutation (SNP) | VAF 9/118 reads (8%) | PolyPhen probably damaging (0.999); catalogued as COSV62417385; called by muse, mutect2
- TMCC2 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.457); catalogued as rs376067050; called by muse, mutect2
- TNS4 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs147274319; called by muse, mutect2, varscan2
- TP53 | c.1015del p.E339Rfs*6 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; called by mutect2, pindel, varscan2
- TTC39B | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52612554; called by muse, mutect2, varscan2
- TULP4 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65578187; called by muse, mutect2, varscan2
- UPF1 | c.925C>G p.L309V | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53198929; called by muse, mutect2, varscan2
- UTRN | c.5345T>A p.I1782K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV62341182; called by muse, mutect2, varscan2
- ZBTB3 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374520382; called by muse, mutect2, varscan2
- ZC3H18 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.102); catalogued as COSV56326307; called by muse, mutect2, varscan2
- ZFR | c.1799A>G p.H600R | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54055349; called by muse, mutect2, varscan2
- ZNF311 | c.288T>A p.N96K | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV65853222; called by muse, mutect2, varscan2
- ZNF582 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV56733065; called by muse, mutect2, varscan2
- ZNF780B | c.2180G>A p.C727Y | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV55466005; called by muse, mutect2, varscan2
- BLM | c.2351_2352del p.Y784* | Frame Shift Del (DEL) | VAF 16/115 reads (14%) | called by mutect2, pindel, varscan2
- CERK | c.1053_1057dup p.V353Afs*82 | Frame Shift Ins (INS) | VAF 16/73 reads (22%) | called by mutect2, varscan2
- DLD | c.1238del p.X413_splice | Splice Site (DEL) | VAF 23/83 reads (28%) | called by mutect2, pindel, varscan2
- ABCA12 | c.1101T>C p.N367= (on ENST00000272895 / NM_173076.3; = p.N49= on NM_015657.3) | Silent (SNP) | VAF 78/150 reads (52%) | catalogued as rs1004902217, COSV55967253; called by muse, mutect2, varscan2
- ABCA13 | c.12339C>T p.T4113= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as rs1013406332, COSV101446748; called by muse, mutect2, varscan2
- ADAM8 | c.243C>T p.S81= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs144120772; called by muse, varscan2
- AQP4 | c.870T>C p.D290= | Silent (SNP) | VAF 48/230 reads (21%) | catalogued as rs1308747630, COSV67219028; called by muse, mutect2, varscan2
- ATP2A3 | c.333C>T p.N111= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs774597476, COSV59231866; called by muse, mutect2, varscan2
- CACNA1G | c.3129G>A p.T1043= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs766326181, COSV61732291; called by mutect2, varscan2
- CARS2 | c.927G>A p.L309= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV57287464; called by mutect2, varscan2
- CCDC191 | c.2245C>T p.L749= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV55674194; called by muse, mutect2
- ELL | c.222G>A p.A74= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs747812361, COSV53214148; called by muse, mutect2, varscan2
- FAM47A | c.1312C>T p.L438= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV60496141; called by muse, mutect2, varscan2
- FBXL18 | c.2022G>A p.A674= | Silent (SNP) | VAF 54/255 reads (21%) | catalogued as rs757464102, COSV66667634; called by muse, mutect2, varscan2
- IL12B | c.96C>G p.V32= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV51455020, COSV51455547; called by muse, mutect2, varscan2
- LRP5 | c.1122C>T p.H374= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as rs764504521, COSV53715250; called by muse, mutect2, varscan2
- MYLK | c.231C>A p.G77= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV60615383; called by muse, mutect2, varscan2
- NAP1L2 | c.840C>T p.G280= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs770051289, COSV65172761; called by muse, mutect2, varscan2
- NSUN7 | c.292C>T p.L98= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV57275086; called by muse, mutect2, varscan2
- PCDHB12 | c.183G>A p.S61= | Silent (SNP) | VAF 56/114 reads (49%) | catalogued as rs782166376, COSV53392772; called by muse, mutect2, varscan2
- PCDHB7 | c.1816C>T p.L606= | Silent (SNP) | VAF 41/228 reads (18%) | catalogued as COSV50792351; called by muse, mutect2, varscan2
- PLEKHA6 | c.2862C>T p.I954= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV55336662; called by muse, mutect2
- PPP1R12A | c.1101A>T p.S367= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV54111198; called by muse, mutect2, varscan2
- RGS9 | c.252C>T p.Y84= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs751169291, COSV52227262; called by muse, mutect2, varscan2
- TRIM16L | c.150G>A p.K50= | Silent (SNP) | VAF 58/116 reads (50%) | catalogued as COSV67459648; called by muse, mutect2, varscan2
- TRIM38 | c.468G>A p.E156= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV62642558; called by muse, mutect2, varscan2
- TRIO | c.4812C>G p.P1604= | Silent (SNP) | VAF 30/54 reads (56%) | catalogued as COSV60088436; called by muse, mutect2, varscan2
- TUBB | c.822C>T p.T274= | Silent (SNP) | VAF 61/151 reads (40%) | catalogued as rs1461698929, COSV58358046; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73850105 C>T | 5'Flank (SNP) | VAF 17/98 reads (17%) | catalogued as rs764227913; called by muse, mutect2, varscan2
- DCHS2 | n.5691G>T | RNA (SNP) | VAF 29/77 reads (38%) | catalogued as COSV61775643; called by muse, mutect2, varscan2
- PGM1 | c.247-5890del | Intron (DEL) | VAF 30/181 reads (17%) | called by mutect2, pindel, varscan2
